TARGET case TARGET-30-PAIRCP — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/4105dc6a-39c8-50a4-95c8-0ac029f82061

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Age at diagnosis: 2.7 years (987 days); Year of diagnosis: 1998; Days to last follow up: 852 days (2.3 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PAIRCP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
